CCDI case PBBXPP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9bb48473-908c-42dd-8991-a46386848f2a

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 18.2 years (6,643 days).

Biospecimens (3 samples)
- Sample 0DK964: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK96E: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DK96R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
